Gene-level copy-number profile of tumor specimen TCGA-DK-A1A7-01A from TCGA case TCGA-DK-A1A7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 67.1 years (24,499 days).
Specimen TCGA-DK-A1A7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.707a2fea-eea7-4156-8e24-52c983734439.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A1A7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 834 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0809e0c-5389-4a7f-9d49-d511c6bb8ec9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,512; copy number 2: 12,044; copy number 3: 21,371; copy number 4: 10,064; copy number 5: 7,258; copy number 6: 2,729; copy number 7: 701; copy number 8: 286; copy number 9: 665; copy number 10: 123; copy number 11: 212; copy number 12: 297; copy number 13: 240; copy number 14: 93; copy number 15: 68; copy number 17: 50; copy number 19: 50; copy number 23: 10; copy number 27: 3; copy number 29: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A1A7-01A-11D-A13V-01): tumor purity 0.74, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:63,022,919–63,981,043, 5 genes: AC113420.1, AC025445.1, AC008558.1, HTR1A, AC122707.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,801 genes in 62 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,839,599–24,187,959, 167 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:33,472,645–34,219,131, 8 genes, copy number 7–11 (within-gene range 4–11): ZSCAN20, AC115285.1, CSMD2, HSPD1P14, HMGB4, CSMD2-AS1, RNA5SP42, C1orf94.
- chr1:38,950,825–40,594,353, 63 genes, copy number 9 (broad region; genes not listed).
- chr1:159,759,170–169,586,588, 275 genes, copy number 8–14 (broad region; genes not listed).
- chr3:9,100,803–13,506,424, 113 genes, copy number 7–10 (broad region; genes not listed).
- chr4:70,637,745–73,944,324, 45 genes, copy number 7–11 (within-gene range 2–11): AC009570.2, JCHAIN, UTP3, RNU6-520P, RNU6-784P, AC009570.1, RUFY3, GRSF1, U6, RNU6-891P, MOB1B, DCK, SLC4A4, AC096713.1, LDHAL6EP, GC, RNA5SP163, AC068721.1, NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1.
- chr4:177,242,539–178,116,861, 10 genes, copy number 8: AC097518.1, NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172, AC103879.1, LINC01098, LINC01099, RNU1-45P.
- chr5:115,489,634–119,070,902, 55 genes, copy number 10: AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1, TMED7, AC008549.2, AC008549.1, H3P24, RNU2-49P, CDO1, ATG12, AP3S1, LINCADL, LVRN, DDX43P1, ARL14EPL, AC034236.1, AC034236.3, AC034236.2, COMMD10, RNU6-644P, HMGN2P27, AC018752.1, SEMA6A, SEMA6A-AS1, RPS14P8, SEMA6A-AS2, RPS17P2, LINC02214, AC010267.1, AC093534.1, AC093534.2, RPL35AP15, AC093295.1, LINC00992, AC114322.1, LINC02147, RPL7L1P4, LINC02208, LINC02148, LINC02216, AC114311.1, LINC02215, RNU7-34P, AC093206.1, DTWD2, PTMAP2, MIR1244-2, AC008629.1, RNU6-373P, AC008629.2, AC008629.3.
- chr6:88,139,864–93,419,559, 65 genes, copy number 13–17 (within-gene range 3–17) (broad region; genes not listed).
- chr6:96,521,595–96,837,477, 9 genes, copy number 23: UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63.
- chr6:122,975,198–126,258,355, 24 genes, copy number 12: AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5.
- chr6:138,464,099–139,860,476, 21 genes, copy number 7–12 (within-gene range 3–12): AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB, AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1, FILNC1.
- chr7:9,614,978–12,440,404, 26 genes, copy number 7: GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3.
- chr7:16,087,525–20,140,453, 52 genes, copy number 9–11: CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1.
- chr8:41,577,187–42,207,709, 18 genes, copy number 13: GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT.
- chr8:67,732,587–74,823,313, 118 genes, copy number 7–15 (within-gene range 5–15) (broad region; genes not listed).
- chr8:97,772,313–105,804,539, 174 genes, copy number 8–13 (within-gene range 4–13) (broad region; genes not listed).
- chr9:23,291,544–25,089,151, 15 genes, copy number 8: AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr9:27,245,680–32,676,520, 49 genes, copy number 7–12 (within-gene range 6–12): LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1.
- chr10:43,900,874–49,115,522, 134 genes, copy number 7–13 (within-gene range 2–13) (broad region; genes not listed).
- chr10:118,932,674–121,928,492, 49 genes, copy number 8 (within-gene range 2–8): LDHAP5, NANOS1, EIF3A, SNORA19, AL355598.1, AL355598.2, DENND10, SFXN4, PRDX3, GRK5, GRK5-IT1, RN7SL749P, AL583824.1, MIR4681, RGS10, AC012468.1, TIAL1, RAD1P1, RPS8P4, BAG3, TXNP1, INPP5F, RN7SL846P, PHACTR2P1, AL133461.1, MCMBP, SEC23IP, MIR4682, NACAP2, AL355298.1, RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1.
- chr10:123,008,979–123,171,875, 5 genes, copy number 10 (within-gene range 2–10): ACADSB, HMX3, HMX2, BUB3, RPS26P39.
- chr10:125,836,337–126,421,879, 11 genes, copy number 8 (within-gene range 2–8): DHX32, Metazoa_SRP, RNU2-42P, FANK1, GNG10P1, FANK1-AS1, ADAM12, RNA5SP328, SAR1AP2, AL589787.2, LINC00601.
- chr10:132,207,492–132,522,449, 8 genes, copy number 7 (within-gene range 5–7): STK32C, LRRC27, PWWP2B, AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165.
- chr12:20,962,768–22,437,041, 25 genes, copy number 9 (within-gene range 4–9): SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P.
- chr12:28,133,249–29,381,189, 18 genes, copy number 7: CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2.
- chr12:30,086,342–33,455,452, 91 genes, copy number 11–13 (broad region; genes not listed).
- chr12:46,358,188–46,972,155, 11 genes, copy number 7: SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1.
- chr12:47,463,087–52,223,813, 217 genes, copy number 7–11 (broad region; genes not listed).
- chr12:66,189,195–73,679,296, 127 genes, copy number 7–19 (broad region; genes not listed).
- chr17:29,203,426–31,901,708, 126 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr17:32,627,739–38,512,385, 201 genes, copy number 7–14 (within-gene range 6–14) (broad region; genes not listed).
- chr18:28,824,652–29,650,440, 6 genes, copy number 7: AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.
- chr19:28,491,864–30,016,612, 36 genes, copy number 15 (within-gene range 5–15): AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr19:37,667,751–40,021,038, 123 genes, copy number 12 (within-gene range 5–12) (broad region; genes not listed).
- chr21:35,887,195–37,661,496, 55 genes, copy number 7–9: PPP1R2P2, LINC01436, RPL23AP3, SETD4, RIMKLBP1, SETD4-AS1, RNU6-992P, AP000688.1, CBR1, AP000688.3, AP000688.2, MEMO1P1, CBR3-AS1, RPS9P1, CBR3, DOP1B, RPL3P1, SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1, AP000695.1, AP000695.2, CLDN14, AP000695.3, PSMD4P1, AP000696.2, AP000696.3, AP000696.1, AP000697.1, SIM2, HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1, AP001437.2, AP001437.1, DYRK1A, AP001407.1.
- chr22:19,479,457–20,416,899, 47 genes, copy number 9 (within-gene range 4–9): CDC45, AC000082.1, CLDN5, LINC00895, AC000077.1, AC000067.1, SEPTIN5, AC000093.1, GP1BB, TBX1, GNB1L, AC000089.1, RTL10, TXNRD2, AC000078.1, COMT, MIR4761, ARVCF, TANGO2, MIR185, AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P.
- chr22:31,816,379–32,113,029, 10 genes, copy number 10 (within-gene range 4–10): AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1.
- chr22:32,474,676–35,377,261, 38 genes, copy number 7–12 (within-gene range 4–12): FBXO7, SYN3, SYN3-AS1, RNA5SP497, Z73495.1, TIMP3, Z83846.1, LINC01640, Z82198.1, Z82198.3, LARGE1, Z82198.2, Z82173.1, MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1.
- chr22:36,281,280–38,794,198, 121 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,204. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
